Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9L1, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9L1-01A (Primary Tumor).

[page 1 of 3]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

ICD-O3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JN 1/23/14

Gross description:

(Prostate gland): Prostate gland: Weight: 78 g, Volume: 65 ml, Size: 5.4 x 4.6 x 4 cm. Adherent seminal vesicles and deferent duct: right side: 2 cm, left side: 2 cm. The surface is marked with green ink on the right side, blue ink on the left side. Total of the cross sections: 3 cm.

Microscopy:

1. Apex right and left: Right 5 tissue blocks, left 3 tissue blocks (total 8 tissue blocks). 4 cross sections: Right 24 tissue blocks, left 24 tissue blocks (total 48 tissue blocks). Basis right and left: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). Seminal vesicles right and left: Right 4 tissue blocks, left 5 tissue blocks (total 9 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 4+5=9, (Gleason 4: 60%, Gleason 5: 40%). Tumor involves both lobes with the main focus on the right side. Maximum tumor diameter: 50 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 8 tissue blocks (maximum invasion length 3 mm, maximal invasion depth 1 mm; Gleason 5). Positive surgical margin in 18 blocks in the apex on both sides, anterior, right side lateral, rectal on both sides, left base and perivesicular on both sides (maximum contact length 6 mm; Gleason 5).

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Infiltration of both seminal vesicles and deferent ducts.

Tumor classification

(in consideration of the parallel report and immunohistochemical analyses):

pT3b, Gleason 4+5=9 (Gleason 4: 60%, Gleason 5: 40%), maximum tumor diameter: 50 mm, tumor volume approx. 45.5 ml (Gleason 4: 27.3 ml, Gleason 5: 18.2 ml), pN1 (1/7), L1, V0, R1

Comments:

Immunohistochemical analyses (D2-40, CD 31) in tissue blocks R3A and R4D revealed lymphatic invasion (L1). No venous invasion was found (V0).

[page 2 of 3]
One macroscopic image for tumor mapping.

See dx discrepancy form for
Gleason 5+5

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason 4+5	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Gleason 5+5	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Frozen sample tissue block submitted to TCGA has a different Gleason score than the frozen tissue block that was used for diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature Date

Source: NCI Genomic Data Commons file 74c3b631-71df-49a9-8aca-8484b56d8e5e (TCGA-ZG-A9L1.1F620B81-F034-4F28-8DE0-6B19D181D24F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).